Somatic mutation profile of tumor specimen TARGET-15-SJMPAL040037-09A.1 (aliquot TARGET-15-SJMPAL040037-09A.1-01D) from TARGET case TARGET-15-SJMPAL040037, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.3 years (5,594 days).
Specimen TARGET-15-SJMPAL040037-09A.1: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6282a920-6438-4b3f-8b5e-7b3f340a9902.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL040037-14A (Bone Marrow Normal), aliquot TARGET-15-SJMPAL040037-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/12dcab84-1522-43f2-b002-556779e18d57

The open-access MAF lists 19 somatic variants for this specimen: 14 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Frame Shift Ins 2, Silent 2, Intron 1, 3'UTR 1, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- OSGIN1 | n.1028+1G>A | Splice Site (SNP) | VAF 6/22 reads (27%) | catalogued as rs768497100; called by muse, mutect2, varscan2
- SSC5D | c.3854C>T p.T1285M | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as rs201172616; called by muse, mutect2, varscan2
- TBX3 | c.1196C>T p.T399M (on ENST00000257566 / NM_016569.4; = p.T379M on NM_005996.4) | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs746953122; called by muse, mutect2, varscan2
- WT1 | c.1189delinsAGATCA p.Q397Rfs*42 | Frame Shift Ins (INS) | VAF 56/128 reads (44%) | catalogued as CM041869, COSV60066810, COSV60071867; called by pindel, varscan2*
- WT1 | c.1102_1103insTGGGGCG p.R368Lfs*7 | Frame Shift Ins (INS) | VAF 44/122 reads (36%) | catalogued as COSV60065714, COSV60066671, COSV60067526, COSV60073219, COSV60075996, COSV60077962, COSV60079089, COSV60085405; called by pindel, varscan2
- CAMTA1 | c.388G>A p.G130R | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHRD | c.2053C>A p.L685I | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.031); called by muse, mutect2
- DDX17 | c.795T>A p.D265E | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.6); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- EPYC | c.360G>T p.L120F | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- HECTD4 | c.4633G>T p.A1545S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- IPCEF1 | c.742G>T p.V248L | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2
- IRF5 | c.262G>C p.A88P | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MUC21 | c.1181A>G p.E394G | Missense Mutation (SNP) | VAF 134/315 reads (43%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- NLRP5 | c.2305C>A p.Q769K | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.029); called by muse, mutect2
- DRC7 | c.1771C>A p.R591= | Silent (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
- LCTL | c.1689G>T p.L563= | Silent (SNP) | VAF 4/35 reads (11%) | called by muse, varscan2
- ABCG2 | chr4:88159265 C>A | 5'Flank (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2
- ARHGEF4 | c.428-16116G>A | Intron (SNP) | VAF 78/178 reads (44%) | called by muse, mutect2, varscan2
- OGG1 | c.*7G>A | 3'UTR (SNP) | VAF 54/132 reads (41%) | called by muse, mutect2, varscan2
